Gene-level copy-number profile of tumor specimen TCGA-AX-A2H5-01A from TCGA case TCGA-AX-A2H5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,757 days).
Specimen TCGA-AX-A2H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.265e67a7-bb8c-45d3-ab08-d3d4cae68468.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A2H5-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1355ae4d-e756-4314-b999-5107f7c7e0cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,522; copy number 2: 38,159; copy number 3: 5,172; copy number 4: 884; copy number 5: 361; copy number 6: 233; copy number 7: 68; copy number 8: 231; copy number 9: 52; copy number 10: 14; copy number 11: 78; copy number 15: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A2H5-01A-11D-A17C-01): tumor purity 0.95, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,321,133–89,325,110, 1 gene: AC137932.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,074 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,465,909–16,468,481, 52 genes, copy number 8 (within-gene range 3–8): CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C, EPHA2, AL451042.2, AL451042.1, ARHGEF19-AS1, ARHGEF19, ANO7L1, AL109627.1, CPLANE2, MT1XP1, FBXO42, SZRD1, RPL22P3, SPATA21, NECAP2, LINC01772.
- chr1:154,564,855–155,566,306, 58 genes, copy number 5: AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4.
- chr1:156,212,982–156,572,604, 18 genes, copy number 7 (within-gene range 2–7): PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3.
- chr2:73,640,723–74,178,898, 24 genes, copy number 5: NAT8, ALMS1P1, NAT8B, TPRKB, AC092653.1, AC092653.2, DUSP11, C2orf78, AC073046.4, STAMBP, AC073046.3, AC073046.2, ACTG2, DGUOK, DGUOK-AS1, RNA5SP97, AC073046.1, TET3, AC110801.1, FNBP1P1, AC073263.1, BOLA3, BOLA3-AS1, MOB1A.
- chr4:4,415,742–7,939,926, 58 genes, copy number 5 (within-gene range 3–5): STX18, STX18-IT1, RPS7P15, STX18-AS1, AC092437.1, LINC01396, MSX1, LDHAP1, RN7SKP113, CYTL1, STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1, C4orf50, MIR378D1, JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274, AFAP1-AS1, AFAP1, AC112254.1.
- chr6:19,143,695–19,839,080, 7 genes, copy number 5 (within-gene range 2–5): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3.
- chr6:43,171,269–43,737,834, 34 genes, copy number 5: SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2.
- chr8:50,490,795–63,234,911, 185 genes, copy number 5–11 (broad region; genes not listed).
- chr8:68,330,955–77,537,290, 136 genes, copy number 8–11 (broad region; genes not listed).
- chr8:78,268,637–80,526,265, 38 genes, copy number 5–7: PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10.
- chr8:127,578,473–135,456,952, 106 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:125,900,421–127,898,645, 52 genes, copy number 6 (within-gene range 3–6): AC005252.1, LINC00939, LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.4, AC068787.1, AC068787.3, AC068787.2, AC068787.5, AC025252.1, Y_RNA, AC025252.2, LINC02411, AC025160.1, AC087894.3, AC087894.2, AC087894.1, LINC02393.
- chr14:74,903,951–75,663,214, 29 genes, copy number 5: RPS6KL1, PGF, EIF2B2, AL049780.1, AL049780.3, MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF, AC007182.1, FLVCR2, AC007182.2, RNA5SP387, AC007182.3.
- chr14:75,649,791–75,660,876, 1 gene, copy number 5: ERG28.
- chr17:28,041,737–28,196,381, 1 gene, copy number 5 (within-gene range 1–5): NLK.
- chr17:28,204,616–29,404,105, 95 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr18:26,098,839–29,650,440, 44 genes, copy number 6–7: RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr19:28,790,812–33,557,470, 103 genes, copy number 7–15 (broad region; genes not listed).
- chr21:43,719,094–44,443,081, 33 genes, copy number 6 (within-gene range 2–6): PDXK, AP001052.1, AP001053.1, CSTB, TMEM97P1, RRP1, AATBC, MYL6P1, AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1, PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1, AIRE, PFKL, AP001062.3, CFAP410, AP001062.1, AP001062.2, AP001063.1, TRPM2.

Autosomal genes at a single copy (total copy number 1): 14,522. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
